Somatic mutation profile of tumor specimen 0DR3MG from CCDI case PBCGBS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.8 years (306 days).
Specimen 0DR3MG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e051953a-9739-43b4-a5c7-c98ecb095943.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DR3L7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7635dd3c-1e9b-41e0-9cf3-a669932aee75

The open-access MAF lists 4 somatic variants for this specimen: 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 2, Silent 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CELF1 | c.807T>A p.A269= (on ENST00000358597 / NM_001376422.1; = p.A265= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 15/294 reads (5%) | catalogued as rs1167537044; called by muse, mutect2
- C8orf76 | c.118-51A>G | Intron (SNP) | VAF 19/428 reads (4%) | catalogued as rs1479255281; called by muse, mutect2
- CD37 | c.-52T>C | 5'UTR (SNP) | VAF 29/68 reads (43%) | called by muse, mutect2, varscan2
- CSHL1 | c.191-98A>T | Intron (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
